Gene-level copy-number profile of tumor specimen HCM-SANG-1317-C20-06A-01D-A80T-32 from HCMI case HCM-SANG-1317-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1317-C20-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09f02e62-746e-4cf1-a04b-1bf1eef51ade.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1317-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/86dcb4a8-a191-4a68-a9de-8ab797227151

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 1,240; copy number 2: 15,626; copy number 3: 18,555; copy number 4: 15,786; copy number 5: 4,718; copy number 6: 2,111; copy number 7: 291; copy number 8: 230; copy number 9: 285; copy number 10: 2; copy number 14: 8; copy number 15: 6.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:71,032,670–71,133,287, 4 genes: GTF2H2, OCLNP1, NAIPP4, CDH12P4.
- chr17:18,415,728–18,551,705, 13 genes (within-gene range 0–1): KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 822 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–16,617,058, 278 genes, copy number 7–9 (broad region; genes not listed).
- chr5:16,617,225–16,623,095, 2 genes, copy number 8: AC022113.1, Y_RNA.
- chr8:33,226,848–33,338,966, 2 genes, copy number 10: AC104027.1, RNU6-528P.
- chr8:33,580,210–34,346,731, 13 genes, copy number 9: RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr10:47,300,197–47,619,480, 16 genes, copy number 7: GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675.
- chr11:55,475,943–55,994,625, 36 genes, copy number 8: OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1.
- chr12:40,692,439–41,072,415, 1 gene, copy number 8 (within-gene range 6–8): CNTN1.
- chr12:40,978,744–41,574,745, 2 genes, copy number 8 (within-gene range 4–8): AC015540.1, PDZRN4.
- chr16:28,973,962–32,363,695, 258 genes, copy number 9–15 (broad region; genes not listed).
- chr16:35,435,303–35,912,516, 44 genes, copy number 7: AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr16:46,702,282–48,471,133, 41 genes, copy number 7: MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1.
- chr16:49,066,567–52,943,464, 88 genes, copy number 7–9 (broad region; genes not listed).
- chr16:90,102,271–90,178,344, 1 gene, copy number 9 (within-gene range 4–9): FAM157C.
- chr16:90,110,574–90,222,851, 4 genes, copy number 9: AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:1,883,524–2,616,635, 8 genes, copy number 8: AP005230.1, AIDAP3, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3.
- chr21:7,744,962–8,454,792, 26 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:44,172,169–44,194,338, 2 genes, copy number 8: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 1,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
